Gene-level copy-number profile of tumor specimen C3L-08296-03 from CPTAC case C3L-08296, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G1; Age at diagnosis: 59.5 years (21,715 days).
Specimen C3L-08296-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7a2baef0-ed50-42c8-8603-1429ae4c2925.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-08296-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/0d8c7bf9-c760-4d64-a605-d33ad3f5a6f0

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 4: 29,193; copy number 5: 28,935; copy number 6: 26; copy number 7: 30; copy number 8: 151; copy number 9: 36; copy number 10: 30.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 66 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:148,383,935–149,432,835, 26 genes, copy number 10: FBXO38, Metazoa_SRP, AC114939.1, HTR4, AC008627.1, ADRB2, SH3TC2, AC116312.1, RNU6-732P, MIR584, SH3TC2-DT, RN7SKP145, ABLIM3, AC012613.1, AC012613.2, AFAP1L1, AC131025.3, GRPEL2, GRPEL2-AS1, PCYOX1L, IL17B, AC131025.1, CARMN, AC131025.2, MIR143, MIR145.
- chr11:69,414,307–70,398,488, 31 genes, copy number 9 (within-gene range 8–9): AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1.
- chr11:70,467,856–71,252,577, 1 gene, copy number 9 (within-gene range 8–9): SHANK2.
- chr11:70,626,441–70,635,658, 1 gene, copy number 9 (within-gene range 8–9): SHANK2-AS1.
- chr11:70,862,790–71,452,868, 6 genes, copy number 9–10: SHANK2-AS3, MIR3664, AP003783.1, ACTE1P, DHCR7, AP002387.1.
- chr11:73,157,946–73,181,724, 1 gene, copy number 10: AP002761.2.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
